CGCI case BLGSP-71-17-00356 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e865ae46-1553-43c6-ad00-3c3d7459f6a1

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 24 years; Vital status: Alive.

Diagnoses (1)
1. Burkitt lymphoma, NOS (Includes all variants): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Classification of tumor: primary; Age at diagnosis: 24.5 years (8,932 days); Year of diagnosis: 2015; Method of diagnosis: Core Biopsy; Ann Arbor pathologic stage: Stage IV; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 862 days (2.4 years); Ann Arbor extranodal involvement: Yes; Max tumor bulk site: Mesenteric lymph nodes; Sites of involvement: Bone, NOS / Abdomen.
   Pathology details: Bone marrow malignant cells: No; Lymph node involved site: Mesenteric.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 862 days (2.4 years); Disease response: With Tumor.
- Follow-up contact recording only the day: day 0.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MYC translocation (FISH): Positive.
- Lactate Dehydrogenase 389 [Blood test normal range upper: 246].

Other clinical attributes
- Day 0: Weight: 77 kg; Height: 183 cm; BMI: 23.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample BLGSP-71-17-00356-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Tissue collection type: Retrospective.
  Slide BLGSP-71-17-00356-01-HE: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 25; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 5.
- Sample BLGSP-71-17-00356-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample BLGSP-71-17-00356-99A: Sample type: Granulocytes; Tissue type: Normal; Specimen type: Granulocytes; Preservation method: Frozen; Tissue collection type: Retrospective.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Treatment outcome first course: Complete Remission/Response; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- Primary pathology: Histologic diagnosis: Burkitt Lymphoma; Extranodal involvment other: Right femoral head, Abdomen.
- Stage record, Ann arbor: B symptoms present indicator: No.
- Tests performed: LDH level: 389.
- Follow-up form: Tumor status: With tumor; Treatment outcome at TCGA followup: Complete Remission/Response; New tumor event diagnosis indicator: No.
